Gene-level copy-number profile of tumor specimen ALCH-B4UC-TTP1-A from ALCHEMIST case ALCH-B4UC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.7 years (22,919 days).
Specimen ALCH-B4UC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e5d0bbc4-0452-4fe1-955d-71630e51b2c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4UC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/7781cc31-9e06-4fc7-8921-3dc670e09677

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 10,210; copy number 2: 44,400; copy number 3: 3,467; copy number 4: 243; copy number 5: 27; copy number 6: 1; copy number 9: 2; copy number 10: 2; copy number 13: 3; copy number 14: 1; copy number 23: 3; copy number 24: 1; copy number 48: 1.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:151,048,292–151,052,756, 1 gene: ASIC3.
- chr9:21,638,285–21,638,676, 1 gene: H3P30.
- chr9:61,330,717–61,582,675, 3 genes: CNTNAP3C, RN7SL462P, AL935212.3.
- chr10:5,638,867–5,666,595, 1 gene: ASB13.
- chr10:131,095,218–131,095,777, 1 gene (within-gene range 0–1): TCERG1L-AS1.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:31,073,860–31,104,799, 2 genes: DDX11, SNORA75.
- chr15:25,184,306–25,201,404, 10 genes (within-gene range 0–2): SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17.
- chr15:25,243,614–25,249,279, 4 genes (within-gene range 0–2): SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43.
- chr17:39,210,541–39,225,945, 1 gene: STAC2.
- chr20:32,858,923–32,961,609, 1 gene: EFCAB8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 41 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,801,717, 3 genes, copy number 13 (within-gene range 2–13): TTC34, AC242022.2, AC242022.1.
- chr1:198,156,994–200,014,795, 24 genes, copy number 5: NEK7, PRR13P1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1, AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P.
- chr1:202,331,657–202,341,980, 1 gene, copy number 5: UBE2T.
- chr11:120,325,296–120,333,686, 1 gene, copy number 6: TLCD5.
- chr14:105,583,731–105,588,395, 1 gene, copy number 24: IGHA2.
- chr14:105,620,506–105,626,066, 1 gene, copy number 5 (within-gene range 2–5): IGHG4.
- chr14:105,664,633–105,669,843, 1 gene, copy number 48 (within-gene range 2–48): IGHGP.
- chr15:85,240,472–85,247,170, 1 gene, copy number 5: GOLGA6L3.
- chr16:28,342,555–28,365,333, 2 genes, copy number 9: NPIPB6, AC138894.3.
- chr21:43,107,942–43,168,646, 1 gene, copy number 23 (within-gene range 2–23): AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 23: AP001631.1, CRYAA.
- chr21:44,107,373–44,210,114, 2 genes, copy number 10 (within-gene range 3–14): PWP2, GATD3A.
- chr21:44,200,602–44,207,399, 1 gene, copy number 14: AP001057.1.

Autosomal genes at a single copy (total copy number 1): 10,192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
